Somatic mutation profile of tumor specimen TCGA-XU-AAY1-01A (aliquot TCGA-XU-AAY1-01A-11D-A428-09) from TCGA case TCGA-XU-AAY1, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 51.4 years (18,777 days).
Specimen TCGA-XU-AAY1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81c5676c-614a-409f-bab0-5b1c50e38723.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-AAY1-10A (Blood Derived Normal), aliquot TCGA-XU-AAY1-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79bfac72-80a5-4a82-906b-9535a0172544

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 18/360 reads (5%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- EP300 | c.3365G>T p.W1122L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ITGA3 | c.645del p.G216Vfs*11 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by pindel, varscan2
- NUDT17 | c.570C>A p.S190= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- TACC2 | c.5253C>T p.C1751= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1312134244; called by muse, mutect2
